Somatic mutation profile of tumor specimen ALCH-AEOH-TTP1-A (aliquot ALCH-AEOH-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AEOH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.1 years (22,682 days).
Specimen ALCH-AEOH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b7fae6d-ffa3-4d8f-8f33-4d97fc6818bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEOH-NB1-A (Blood Derived Normal), aliquot ALCH-AEOH-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0383978c-e322-4866-aac8-585c889b1483

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, Intron 4, Nonsense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.4219G>A p.V1407I | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.052); catalogued as rs747329081; called by muse, mutect2, varscan2
- CDH3 | c.1718C>G p.S573C | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99868047; called by muse, mutect2
- EDEM3 | c.2731G>C p.D911H | Missense Mutation (SNP) | VAF 9/250 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV58927797; called by muse, mutect2
- IRF4 | c.665C>G p.A222G | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV66705706; called by muse, mutect2, varscan2
- PDZD4 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99381682; called by muse, mutect2, varscan2
- PTPRN2 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as rs532802114, COSV67026733; called by mutect2, varscan2
- RAB3GAP2 | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 40/666 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs764594200; called by muse, mutect2
- RERE | c.3401A>G p.Y1134C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as rs756826589; called by muse, mutect2
- RLIM | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 10/277 reads (4%) | catalogued as COSV60325116; called by muse, mutect2
- AP5B1 | c.174G>T p.M58I | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- CARS2 | c.1357A>G p.I453V | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DHX29 | c.1246A>T p.K416* | Nonsense Mutation (SNP) | VAF 45/182 reads (25%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.446T>C p.L149S | Missense Mutation (SNP) | VAF 103/327 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFL1 | c.2932C>T p.Q978* | Nonsense Mutation (SNP) | VAF 38/148 reads (26%) | called by muse, mutect2, varscan2
- FAM180A | c.375G>T p.R125S | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- HIVEP1 | c.2874G>A p.M958I | Missense Mutation (SNP) | VAF 69/322 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MIA3 | c.2947G>A p.E983K | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2
- NCKAP5 | c.1288A>T p.M430L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- OS9 | c.1043A>T p.N348I | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- POLR2I | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SRRM2 | c.3814C>A p.P1272T | Missense Mutation (SNP) | VAF 9/250 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); called by muse, mutect2
- ADGRL2 | c.261C>T p.P87= | Silent (SNP) | VAF 55/258 reads (21%) | catalogued as rs772280788, COSV54680898; called by muse, mutect2, varscan2
- DCBLD1 | c.2022C>A p.L674= | Silent (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- SMG6 | c.1251A>G p.L417= | Silent (SNP) | VAF 25/310 reads (8%) | catalogued as rs1459499618; called by muse, mutect2
- SPINT3 | c.45C>T p.L15= | Silent (SNP) | VAF 15/319 reads (5%) | called by muse, mutect2
- ICA1 | c.903-213A>G | Intron (SNP) | VAF 56/252 reads (22%) | catalogued as rs1027042725; called by muse, mutect2, varscan2
- IFT122 | c.2988-28C>T | Intron (SNP) | VAF 14/242 reads (6%) | called by muse, mutect2
- KSR1 | c.1510+508T>A | Intron (SNP) | VAF 46/190 reads (24%) | called by muse, mutect2, varscan2
- STARD9 | c.12765-19G>A | Intron (SNP) | VAF 60/174 reads (34%) | catalogued as rs758653146; called by muse, mutect2, varscan2
